Gene-level copy-number profile of tumor specimen TCGA-DX-AB2Q-01A from TCGA case TCGA-DX-AB2Q, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 65.0 years (23,748 days).
Specimen TCGA-DX-AB2Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.4c725b73-5279-4559-bc1b-d1b7a08b5740.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f7d1fc3c-7050-4d18-8eb5-d93af2e7aab1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 132; copy number 2: 7,562; copy number 3: 7,256; copy number 4: 16,398; copy number 5: 13,978; copy number 6: 5,839; copy number 7: 2,585; copy number 8: 2,090; copy number 9: 2,312; copy number 10: 151; copy number 11: 850; copy number 12: 16; copy number 13: 91; copy number 14: 97; copy number 15: 19; copy number 16: 16; copy number 17: 39; copy number 19: 28; copy number 21: 10; copy number 23: 119; copy number 32: 78; copy number 37: 4; copy number 39: 10; copy number 53: 82; copy number 77: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB2Q-01A-11D-A38Y-01): tumor purity 0.6, ploidy 4.56, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–477,967, 15 genes (within-gene range 0–7): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1.
- chr16:83,899,115–84,042,795, 5 genes (within-gene range 0–2): MLYCD, AC009119.2, OSGIN1, NECAB2, SLC38A8.
- chr17:7,591,230–7,711,372, 7 genes (within-gene range 0–6): FXR2, SHBG, SAT2, ATP1B2, TP53, WRAP53, EFNB3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,925 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:9,703,754–18,888,662, 118 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr4:28,580,991–49,062,081, 242 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr5:22,754,227–45,895,970, 336 genes, copy number 9 (broad region; genes not listed).
- chr7:53,366,058–57,245,931, 137 genes, copy number 14–39 (broad region; genes not listed).
- chr7:63,011,463–65,463,438, 132 genes, copy number 11 (broad region; genes not listed).
- chr7:76,959,835–97,599,260, 257 genes, copy number 9 (broad region; genes not listed).
- chr8:35,862,123–36,936,125, 15 genes, copy number 15 (within-gene range 5–15): AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8.
- chr8:37,559,992–41,440,419, 92 genes, copy number 9–32 (broad region; genes not listed).
- chr8:46,028,804–50,860,062, 76 genes, copy number 9 (broad region; genes not listed).
- chr8:70,669,339–85,977,154, 229 genes, copy number 9–11 (within-gene range 8–11) (broad region; genes not listed).
- chr8:86,016,819–86,043,507, 2 genes, copy number 9: AC023194.1, AC023194.2.
- chr8:88,326,836–88,887,573, 1 gene, copy number 9 (within-gene range 8–9): AC090578.1.
- chr8:88,808,318–91,917,918, 36 genes, copy number 9: AC090578.2, AC090578.3, RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1.
- chr9:29,824,742–29,826,711, 1 gene, copy number 9: ME2P1.
- chr10:27,504,174–28,941,910, 31 genes, copy number 9–13: RAB18, LINC02680, MKX, MKX-AS1, ARMC4, RN7SKP132, RPL36AP55, AL390866.1, MRPS21P5, MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1, WAC, RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI, LINC01517, AL355376.1, RNU6-270P, LINC00837, AL355376.2, RNA5SP308, RPL21P93.
- chr11:49,433,480–49,810,419, 2 genes, copy number 11–12 (within-gene range 7–12): AC135977.1, AC136759.1.
- chr11:74,807,739–74,949,200, 1 gene, copy number 23 (within-gene range 8–23): XRRA1.
- chr11:74,876,286–79,441,030, 118 genes, copy number 23 (within-gene range 2–23) (broad region; genes not listed).
- chr11:81,821,272–82,718,299, 1 gene, copy number 13 (within-gene range 2–13): MIR4300HG.
- chr11:82,603,529–83,423,516, 31 genes, copy number 13: AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr11:83,643,602–83,815,263, 3 genes, copy number 13: DLG2-AS2, AP002370.1, LDHAL6DP.
- chr11:98,565,074–106,469,296, 105 genes, copy number 37–77 (broad region; genes not listed).
- chr12:20,695,332–34,249,958, 261 genes, copy number 9–10 (broad region; genes not listed).
- chr14:21,941,128–22,509,406, 80 genes, copy number 11 (broad region; genes not listed).
- chr16:17,825,252–17,933,275, 2 genes, copy number 10: AC025277.1, RPL7P47.
- chr16:17,961,597–17,962,370, 1 gene, copy number 10: AC010601.2.
- chr17:55,526,964–56,511,659, 8 genes, copy number 10 (within-gene range 8–10): AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1.
- chr17:58,218,548–61,392,838, 112 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr17:61,452,404–63,005,152, 42 genes, copy number 11–15: TBX4, AC005901.1, NACA2, BRIP1, INTS2, Y_RNA, MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA, Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7, METTL2A, TLK2, AC008026.1, AC008026.3, AC080038.2, AC080038.1, MRC2, Y_RNA, AC080038.3, RNU6-446P, AC005821.1, MARCHF10, AC005821.2, MARCHF10-DT, PRELID3BP3, AC005972.3, MIR633, TRMT112P3, AC005972.1, AC005972.2.
- chr18:6,729,716–8,406,861, 18 genes, copy number 10 (within-gene range 5–10): ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1, AP001095.1, PTPRM, AP000897.2, AP000897.1, U3, AP005900.1.
- chr20:35,002,404–43,716,495, 199 genes, copy number 9–19 (within-gene range 5–19) (broad region; genes not listed).
- chr21:15,928,296–16,645,467, 1 gene, copy number 17 (within-gene range 2–17): MIR99AHG.
- chr21:16,284,696–18,760,320, 38 genes, copy number 11–17 (within-gene range 5–17): SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X.
- chr22:19,291,969–50,801,309, 1,197 genes, copy number 9–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 132. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
